Gene-level copy-number profile of tumor specimen TCGA-04-1343-01A from TCGA case TCGA-04-1343, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.4 years (26,428 days).
Specimen TCGA-04-1343-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2ea95bbb-00cd-491e-814e-25360d715683.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1343-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e6e1594-1001-4a1f-8e7e-1b059b1b375c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,310; copy number 2: 17,226; copy number 3: 21,330; copy number 4: 12,657; copy number 5: 2,474; copy number 6: 1,099; copy number 7: 706; copy number 8: 662; copy number 9: 303; copy number 11: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1343-01A-01D-0428-01): tumor purity 0.61, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,722 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:142,407,657–146,606,216, 54 genes, copy number 7: RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1, RNU7-47P, PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1, PBX2P1, SLC9A9, AC131210.1, SLC9A9-AS1, SLC9A9-AS2, GAPDHP47, ST13P15, AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:146,921,795–146,996,713, 2 genes, copy number 7: LINC02010, RNU6-505P.
- chr3:177,294,442–198,222,513, 472 genes, copy number 8–9 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr18:10,666,483–11,489,369, 10 genes, copy number 8: PIEZO2, AP001180.4, KIAA0895LP1, MIR6788, AP005120.1, AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928.
- chr18:22,699,481–28,177,946, 95 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:47,160,838–64,313,132, 414 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,505. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
